FM case AD565 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/dbfc6f1c-49c4-4a19-817a-bcf4a3474413

Female, 66.2 years: diagnosis not reported by GDC; metastasis biopsied or resected from the thorax. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Metastatic.
